Surgical pathology report (de-identified scan), TCGA case TCGA-W5-AA2J, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Mayo Clinic Rochester, specimen TCGA-W5-AA2J-01A (Primary Tumor).

Female
Surgery Date:

DIAGNOSIS:

A. Lymph nodes, hepatic hilar, biopsy: Multiple (4) lymph nodes are negative for tumor.

B. Hepatic duct, left margin, excision: Negative for tumor.

C. Liver, left lobe, partial hepatectomy: Cholangiocarcinoma, moderately differentiated (grade 2 of 4), forming two masses, ranging from 1.5 cm to 0.9 cm in greatest microscopic dimension. Multiple additional microscopic foci of periductal infiltrating carcinoma along the duct associated with moderate to severe dysplasia are present. The tumor is confined to hepatic parenchyma.

The hepatic parenchymal resection margin is negative for tumor (tumor-free margin, 4.5 cm grossly). Major vessel invasion is absent. Microscopic (small vessel) invasion is absent. No regional lymph nodes identified in specimen. The non-neoplastic hepatic parenchyma will be reviewed on permanent sections with special stains and the result will be reported in an addendum.

D. Gallbladder, cholecystectomy: Benign gallbladder with chronic inflammation.

ICD-O-3

C cholangiocarcinoma 8160/3

Site: Intrahepatic bile duct C22.1

Op 5/5/14

Source: NCI Genomic Data Commons file 5bbd405f-505d-4f70-8e80-6bfe0c5a3952 (TCGA-W5-AA2J.FD57F767-3647-411C-ACC7-314F20DA9255.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).